CCDI case PBCAYC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/51d00f8b-34e7-4b4c-a034-036ef1e8da53

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.9 years (4,353 days).

Biospecimens (4 samples)
- Sample 0DMUXH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DMUY4, 0DMUZA (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNCON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
